Somatic mutation profile of tumor specimen MMRF_2095_1_BM_CD138pos (aliquot MMRF_2095_1_BM_CD138pos_T1_KHS5U_L08642) from MMRF case MMRF_2095, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 84.6 years (30,912 days).
Specimen MMRF_2095_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2bf9266-7665-4515-a0ac-df50338f377b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2095_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2095_1_PB_Whole_C2_KHS5U_L08643; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e298e75-f6a9-4e58-96b3-2f125bc219e5

The open-access MAF lists 65 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 24, Missense Mutation 20, 5'Flank 5, Intron 5, Silent 4, Frame Shift Del 2, 5'UTR 2, 3'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.13636T>G p.F4546V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779396324; called by muse, mutect2
- BAIAP2L2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs1044325960; called by muse, mutect2
- CCDC182 | c.64del p.M22* | Frame Shift Del (DEL) | VAF 56/128 reads (44%) | catalogued as rs1567992795; called by mutect2, pindel, varscan2
- CLDN1 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766730136; called by muse, mutect2, varscan2
- H3-5 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 106/260 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.481); catalogued as rs750008087; called by muse, mutect2, varscan2
- IGHV2-70 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs777304363; called by muse, varscan2
- IGLV3-1 | c.62A>C p.Y21S | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs145382269; called by muse, mutect2, varscan2
- KALRN | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); catalogued as rs755363438, COSV53762509; called by muse, mutect2, varscan2
- PCDH15 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs770931801; called by muse, mutect2, varscan2
- RDH16 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs202131585; called by muse, mutect2, varscan2
- STEAP2 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 80/179 reads (45%) | catalogued as rs759069761, COSV55291911; called by muse, mutect2, varscan2
- TMCC3 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs747846295, COSV99705684; called by muse, mutect2, varscan2
- TNKS2 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs201015037, COSV65415376; called by muse, mutect2, varscan2
- AKAP9 | c.8112T>G p.H2704Q (on ENST00000359028; = p.H2680Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALDH1L1 | c.1564C>A p.H522N | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRYZ | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- HPD | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- LAMA5 | c.10316T>C p.L3439P | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- NPHP1 | c.1495A>G p.S499G (on ENST00000393272 / NM_207181.4; = p.S500G on NM_000272.5) | Missense Mutation (SNP) | VAF 110/236 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PTPN18 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SETD9 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TRIM24 | c.1673dup p.M558Ifs*38 (on ENST00000343526 / NM_015905.3; = p.M524Ifs*38 on NM_003852.4) | Frame Shift Ins (INS) | VAF 61/181 reads (34%) | called by mutect2, pindel, varscan2
- UGT1A5 | c.310_311del p.E104Tfs*8 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
- WDFY2 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CHRNG | c.378C>T p.L126= | Silent (SNP) | VAF 63/140 reads (45%) | called by muse, mutect2, varscan2
- ENC1 | c.1224A>C p.S408= | Silent (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- MICAL2 | c.1380T>C p.F460= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as rs773041943; called by muse, mutect2, varscan2
- NLRP9 | c.2208C>T p.S736= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as rs141420832; called by muse, mutect2, varscan2
- ALG11 | c.*3961A>G | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- B3GALNT1 | c.*1272G>A | 3'UTR (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021462 G>A | 5'Flank (SNP) | VAF 55/104 reads (53%) | catalogued as rs958486224, COSV55847618, COSV55848399; called by muse, mutect2, varscan2
- BRWD1 | c.-296C>A | 5'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- C14orf119 | c.*390G>A | 3'UTR (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- CCDC152 | c.*582A>G | 3'UTR (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- COA8 | c.-8G>A | 5'UTR (SNP) | VAF 22/47 reads (47%) | catalogued as rs1301344977; called by muse, mutect2, varscan2
- DCDC1 | c.2715+8887T>A | Intron (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- FAM135B | c.*341T>G | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- FER1L6 | c.2985+58C>A | Intron (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- GAS1 | c.*645G>A | 3'UTR (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- HDAC2 | c.*2863T>C | 3'UTR (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- HRG | c.*265_*267del | 3'UTR (DEL) | VAF 20/65 reads (31%) | called by pindel, varscan2
- HYPK | c.*90A>C | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- IL31 | c.*62T>C | 3'UTR (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- JAZF1 | c.*1681T>C | 3'UTR (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*1052C>A | 3'UTR (SNP) | VAF 25/59 reads (42%) | catalogued as COSV99715905; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851301 A>C | 5'Flank (SNP) | VAF 51/115 reads (44%) | catalogued as rs756302675; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851302 G>C | 5'Flank (SNP) | VAF 53/114 reads (46%) | catalogued as rs533550579; called by muse, mutect2, varscan2
- NGEF | chr2:233015872 T>C | 5'Flank (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- PCDH10 | c.*756C>A | 3'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- PDCL | c.*1757A>G | 3'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- RIIAD1 | chr1:151719653 T>G | 5'Flank (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- RNF144B | c.*2586del | 3'UTR (DEL) | VAF 4/28 reads (14%) | catalogued as rs200074356; called by pindel, varscan2
- SETD4 | c.-36-150G>A | Intron (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- SHC1 | c.1624-347C>T | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- SREK1 | chr5:66180720 G>A | 3'Flank (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- TAB2 | c.*620C>T | 3'UTR (SNP) | VAF 15/36 reads (42%) | catalogued as rs887560131; called by muse, mutect2, varscan2
- TCERG1 | c.*417A>T | 3'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as rs1012736223, COSV57033522; called by muse, mutect2, varscan2
- THNSL2 | c.*235G>A | 3'UTR (SNP) | VAF 11/47 reads (23%) | catalogued as rs570512560; called by muse, mutect2, varscan2
- TRAF5 | c.*1440T>C | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- TRAF5 | c.*1441T>A | 3'UTR (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- TTC3 | c.*1420_*1422del | 3'UTR (DEL) | VAF 28/48 reads (58%) | catalogued as rs1242254352; called by mutect2, pindel, varscan2
- UBQLN1 | c.*233del | 3'UTR (DEL) | VAF 29/64 reads (45%) | catalogued as COSV99973503; called by mutect2, pindel, varscan2
- WDCP | c.*790T>C | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, varscan2
- WDCP | c.*734T>C | 3'UTR (SNP) | VAF 22/56 reads (39%) | called by muse, varscan2
- ZACN | c.544+283A>C | Intron (SNP) | VAF 7/181 reads (4%) | called by muse, mutect2
